HCMI case HCM-BROD-0957-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c24da6e-5546-4037-8ef6-61fc5c2c0901

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1972; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 42.7 years (15,582 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIB; AJCC pathologic T: T2a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C79.8; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 46.5 years (16,995 days); Days to diagnosis: 1,413 days (3.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Abemaciclib + Carboplatin + Pembrolizumab + Pemetrexed; Treatment intent type: Maintenance Therapy; Days to treatment start: 0 days; Days to treatment end: 572 days (1.6 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,410.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0957-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0957-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
